Somatic mutation profile of tumor specimen TCGA-AN-A0XT-01A (aliquot TCGA-AN-A0XT-01A-11D-A10G-09) from TCGA case TCGA-AN-A0XT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.2 years (19,794 days).
Specimen TCGA-AN-A0XT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c136a2e-057a-46dd-a642-5e515d10a569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XT-10A (Blood Derived Normal), aliquot TCGA-AN-A0XT-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88353b76-7d69-4242-921c-3df94bcd08a4

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 7, Missense Mutation 7, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 32/52 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 32/44 reads (73%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS17 | c.2005G>A p.G669S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749915048, COSV51473143; called by muse, mutect2, varscan2
- APLF | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs199832884, COSV58148267; called by muse, mutect2
- HTR5A | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs866283043, COSV55280411; called by muse, mutect2, varscan2
- LPAR6 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57296141; called by muse, mutect2, varscan2
- POLR2F | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.834); catalogued as COSV50777651; called by muse, mutect2, varscan2
- TULP3 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.017); catalogued as COSV68117321; called by muse, mutect2, varscan2
- AGO3 | c.2253C>T p.L751= | Silent (SNP) | VAF 87/200 reads (44%) | catalogued as rs750383007, COSV55790929; called by muse, mutect2, varscan2
- DHDH | c.147C>T p.H49= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV55481281; called by muse, mutect2, varscan2
- LMBR1 | c.309C>T p.S103= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as rs1465890734, COSV62218244; called by muse, mutect2, varscan2
- RPL4 | c.321C>T p.T107= | Silent (SNP) | VAF 108/286 reads (38%) | catalogued as COSV57178240; called by muse, mutect2, varscan2
- STKLD1 | c.246C>T p.H82= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as rs369047700; called by muse, mutect2
- TMED4 | c.52C>T p.L18= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56941276; called by muse, mutect2, varscan2
- TREM1 | c.705G>A p.*235= | Silent (SNP) | VAF 60/179 reads (34%) | catalogued as COSV55147731; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2658C>T | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as rs747700670, COSV55998655; called by muse, mutect2, varscan2
- FOXP1 | c.-298+39465G>C | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59516402; called by muse, mutect2, varscan2
